Somatic mutation profile of tumor specimen TCGA-HC-7231-01A (aliquot TCGA-HC-7231-01A-11D-2114-08) from TCGA case TCGA-HC-7231, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,278 days).
Specimen TCGA-HC-7231-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62678881-40bd-4e02-875f-3b7f6feda42c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7231-10A (Blood Derived Normal), aliquot TCGA-HC-7231-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3730e30c-1995-435f-aec2-6da97c59736b

The open-access MAF lists 37 somatic variants for this specimen: 22 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 14, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC020765.6 | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV63456971; called by muse, mutect2
- ANK1 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs907775044, COSV55877464; called by muse, mutect2, varscan2
- CHL1 | c.2732C>T p.T911I (on ENST00000397491 / NM_001253387.1; = p.T927I on NM_006614.4) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56589899; called by muse, mutect2, varscan2
- CPPED1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as rs202146873; called by muse, mutect2, varscan2
- CPPED1 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as COSV55496591; called by muse, mutect2, varscan2
- DMBT1 | c.6477C>A p.N2159K (on ENST00000338354 / NM_001377530.1; = p.N1402K on NM_004406.3) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV57539068; called by muse, mutect2
- FOXK2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as rs1412570873, COSV58877937; called by muse, mutect2, varscan2
- GRM5 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59598170; called by muse, mutect2, varscan2
- HLF | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV56829286; called by muse, mutect2, varscan2
- HSPA8 | c.1729A>G p.I577V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); catalogued as COSV57083299; called by muse, mutect2, varscan2
- KAT6B | c.4379T>G p.L1460* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV54742736, COSV54744639; called by muse, mutect2
- MCMBP | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.663); catalogued as rs1051951158, COSV63508850; called by muse, mutect2
- NCAN | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs757000546, COSV53048696; called by muse, mutect2, varscan2
- PHF8 | c.1096T>G p.F366V (on ENST00000357988 / NM_001184896.1; = p.F330V on NM_015107.3) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV57679206; called by muse, mutect2, varscan2
- PRRC2C | c.8231C>T p.T2744M (on ENST00000367742; = p.T2742M on NM_015172.4) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs760628219, COSV58903064; called by muse, mutect2, varscan2
- RNF181 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV100110547, COSV57817626; called by muse, mutect2
- SLC16A7 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs543596862, COSV53893187, COSV53900554; called by muse, mutect2, varscan2
- TSC2 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796053512, COSV54755895; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- UNC45B | c.1415C>A p.T472N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV52093788; called by muse, mutect2
- WDR49 | c.229C>A p.L77I (on ENST00000308378 / NM_001366158.1; = p.L418I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs201698456; called by muse, mutect2, varscan2
- CASZ1 | c.3547del p.H1183Tfs*32 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- SETDB1 | c.1722dup p.P575Tfs*18 | Frame Shift Ins (INS) | VAF 36/145 reads (25%) | called by mutect2, pindel, varscan2
- AMDHD2 | c.1155C>T p.L385= (on ENST00000293971 / NM_001330449.2; = p.L415= on NM_015944.4) | Silent (SNP) | VAF 77/227 reads (34%) | catalogued as rs749749353, COSV53550171; called by muse, mutect2, varscan2
- CAMK2B | c.1881C>T p.D627= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1463275169, COSV51657646, COSV51660743; called by muse, mutect2, varscan2
- DCAF12L1 | c.672G>A p.P224= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as rs770105970, COSV64421435; called by muse, mutect2, varscan2
- E2F7 | c.2295G>A p.P765= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs754206014, COSV59738570; called by muse, mutect2, varscan2
- FOXRED2 | c.1113C>T p.Y371= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs144879175; called by muse, mutect2, varscan2
- IMPG2 | c.1404G>A p.S468= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs760482754, COSV51975691; called by muse, mutect2, varscan2
- IRF2BP1 | c.393T>C p.T131= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV56193194; called by muse, mutect2
- LRRC32 | c.735C>T p.L245= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV52632250; called by muse, mutect2, varscan2
- MYH8 | c.5391G>A p.Q1797= | Silent (SNP) | VAF 8/175 reads (5%) | catalogued as COSV67962348; called by muse, mutect2
- NPVF | c.547C>T p.L183= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs572195157, COSV56060415; called by muse, mutect2, varscan2
- PCDHA11 | c.1563G>A p.P521= | Silent (SNP) | VAF 24/237 reads (10%) | catalogued as rs782557554, COSV56488573, COSV56555599; called by muse, mutect2
- SIM1 | c.1557C>A p.V519= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV53490468, COSV53493873; called by muse, mutect2
- STX3 | c.442C>A p.R148= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV55696551; called by muse, mutect2
- VGLL3 | c.654C>T p.S218= | Silent (SNP) | VAF 42/161 reads (26%) | catalogued as rs368628256, COSV67352704; called by muse, mutect2, varscan2
- TMEM183B | n.686C>G | RNA (SNP) | VAF 83/242 reads (34%) | called by muse, mutect2, varscan2
